Somatic mutation profile of tumor specimen 0DO5FL from CCDI case PBCBKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Endocervix; Age at diagnosis: 18.5 years (6,755 days).
Specimen 0DO5FL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af797718-cc23-4471-ad83-9193c6b70dd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO5DW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96f6f0c5-5b8d-498a-b32b-7ab265dc56c0

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 19/294 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2
- CTNNA3 | c.2289G>C p.Q763H | Missense Mutation (SNP) | VAF 19/444 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV101041265; called by muse, mutect2
- NRXN3 | c.673C>G p.Q225E (on ENST00000557594 / NM_001272020.2; = p.Q857E on NM_004796.6) | Missense Mutation (SNP) | VAF 32/766 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR4X1 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 36/897 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRR23A | c.432A>C p.A144= | Silent (SNP) | VAF 19/584 reads (3%) | called by muse, mutect2
- TUBB4A | c.*85C>A | 3'UTR (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99900158; called by muse, mutect2
